Somatic mutation profile of tumor specimen BA2525D (aliquot aq-BA2525D) from BEATAML1.0 case 2543, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,516 days).
Specimen BA2525D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6ff7346-b31e-40e8-ae09-4ba21994fbb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3031D (Solid Tissue Normal), aliquot aq-BA3031D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9602f266-1f56-4850-8bc6-c5813cd06799

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MXRA5 | c.4460G>A p.R1487Q | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs745491907, COSV99478889; called by muse, mutect2
- TGM4 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as rs199660118, COSV56093266; called by muse, mutect2
- LRRC7 | c.1184T>C p.L395S (on ENST00000651989 / NM_001370785.2; = p.L362S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TAB2 | c.238T>G p.L80V | Missense Mutation (SNP) | VAF 17/495 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); called by muse, mutect2
- KCNB1 | c.111C>T p.V37= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV65568804; called by muse, mutect2
- PRKAG3 | c.*25G>A | 3'UTR (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
